Gene-level copy-number profile of tumor specimen TCGA-30-1859-01A from TCGA case TCGA-30-1859, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; Tumor grade: G3; Age at diagnosis: 56.1 years (20,498 days).
Specimen TCGA-30-1859-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.c0cc1915-31e9-4ed6-bfc9-405b6a8d2f10.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-30-1859-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5366243d-a77c-4884-ad26-7362bb29da7a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,065; copy number 2: 20,488; copy number 3: 21,900; copy number 4: 14,063; copy number 5: 892; copy number 6: 1,049; copy number 7: 82; copy number 9: 20; copy number 10: 89; copy number 13: 59; copy number 14: 7; copy number 19: 68; copy number 24: 2; copy number 25: 8; copy number 26: 1; copy number 34: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-30-1859-01): tumor purity 0.97, ploidy 3.07, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 353 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:90,295,507–104,019,748, 99 genes, copy number 10–26 (broad region; genes not listed).
- chr6:104,687,241–105,180,014, 11 genes, copy number 25–34: AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3.
- chr6:106,360,717–106,975,627, 14 genes, copy number 34 (within-gene range 2–34): CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24.
- chr14:18,333,726–19,936,757, 82 genes, copy number 7 (broad region; genes not listed).
- chr14:19,975,444–21,783,503, 127 genes, copy number 13–19 (broad region; genes not listed).
- chr19:7,348,943–7,647,873, 20 genes, copy number 9: AC119396.1, AC008878.3, AC119396.2, ARHGEF18, PEX11G, TEX45, AC008878.1, ZNF358, AC008878.4, MCOLN1, AC008878.2, PNPLA6, CAMSAP3, MIR6792, XAB2, PET100, AC008763.2, PCP2, AC008763.1, STXBP2.

Autosomal genes at a single copy (total copy number 1): 1,065. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
